TCGA case TCGA-EJ-A8FO — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Prostate gland; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b751083d-be6d-45da-be97-a6d41d8ebe97

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 51.7 years (18,875 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; AJCC clinical T: T3a; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 37.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 156 days; Disease response: Tumor Free.
- Days to follow up: 282 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.1 ng/mL (day 156).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EJ-A8FO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-EJ-A8FO-01A-02-TSB: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EJ-A8FO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-EJ-A8FO-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 500 mg.
  Slide TCGA-EJ-A8FO-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 75; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma, Other Subtype; Histologic diagnosis other: acinar and ductal; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Stage record, Psa: PSA most recent results: 0.1.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 3.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 282 days; disease-specific survival: no event (censored), 282 days; disease-free interval: no event (censored), 282 days; progression-free interval: no event (censored), 282 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EJ-A8FO-01A-21D-A363-01): tumor purity 0.29, ploidy 2, whole-genome doublings 0.
